Somatic mutation profile of tumor specimen SM-JU33P (aliquot 7316UP-213) from CPTAC case C243048, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU33P: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6991554c-3d7c-49ba-9957-fc4f14c85314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105206 (Blood Derived Normal), aliquot 7316UP-1282-1105206; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39e65d4b-264e-4c34-a55f-a6fccfc58f5a

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Intron 2, Splice Site 1, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/250 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- C1orf94 | c.577G>A p.V193I (on ENST00000488417 / NM_001134734.2; = p.V3I on NM_032884.5) | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs773093561; called by muse, mutect2, varscan2
- COLEC10 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV100250951, COSV60522639; called by muse, mutect2
- GBA2 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62306518; called by muse, varscan2
- GBA2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs756503362; called by muse, mutect2, varscan2
- KLHL10 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV53174344; called by muse, mutect2
- KRTAP4-7 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs554015981; called by muse, mutect2, varscan2
- LCOR | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs201744063; called by muse, mutect2, varscan2
- MCM8 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1365419029, COSV99495753; called by muse, mutect2, varscan2
- NME8 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs779582375; called by muse, mutect2, varscan2
- THSD7B | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs769700307, COSV55691630; called by muse, mutect2
- TNKS2 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104424932; called by muse, mutect2
- VWDE | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51725806; called by muse, mutect2, varscan2
- ATP8B1 | c.571T>C p.W191R | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP61 | c.2891A>G p.D964G | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- GAREM1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 72/945 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- GAREM1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 69/910 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GBA2 | c.1523G>C p.R508T | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- IRAG1 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ITGA7 | c.1202T>C p.V401A (on ENST00000555728; = p.V357A on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PLAGL1 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2
- PRSS16 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 6/39 reads (15%) | called by pindel, varscan2*
- TP53 | c.656_657dup p.Y220Pfs*28 | Frame Shift Ins (INS) | VAF 182/359 reads (51%) | called by mutect2, pindel, varscan2
- UTRN | c.5866A>G p.K1956E | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR70 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ZNF653 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DKKL1 | c.573C>T p.S191= | Silent (SNP) | VAF 39/241 reads (16%) | catalogued as rs375202437, COSV55561777; called by muse, mutect2, varscan2
- EHD4 | c.762C>G p.R254= | Silent (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- MYO15A | c.2514G>A p.S838= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs953132094; called by muse, mutect2, varscan2
- NEK10 | c.2727G>T p.S909= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV55355950; called by muse, mutect2, varscan2
- OR5AR1 | c.669T>A p.V223= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- PNISR | c.2061A>G p.E687= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs1476804612; called by muse, mutect2, varscan2
- SYDE1 | c.843G>A p.A281= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1343918919, COSV54621634; called by muse, mutect2
- TLN1 | c.6375G>A p.V2125= | Silent (SNP) | VAF 48/252 reads (19%) | catalogued as COSV59205102; called by muse, mutect2, varscan2
- EYS | c.1767-6584C>T | Intron (SNP) | VAF 102/264 reads (39%) | catalogued as rs753104022, COSV101005079; called by mutect2, varscan2
- RNA5-8SP2 | chr16:34159745 G>A | 5'Flank (SNP) | VAF 88/244 reads (36%) | catalogued as rs796298062; called by muse, mutect2, varscan2
- SLC25A13 | c.1019-15A>G | Intron (SNP) | VAF 116/266 reads (44%) | called by muse, mutect2, varscan2
